Somatic mutation profile of cancer-model specimen HCM-CSHL-1270-C18-85N (3D Organoid; aliquot HCM-CSHL-1270-C18-85N-01D-A905-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1270-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GX; Age at diagnosis: 61.6 years (22,485 days).
Specimen HCM-CSHL-1270-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7bfe3b4-3697-4714-9766-da89e0417eba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1270-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-1270-C18-11A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8c8f70-2cd7-4dae-a171-b01da4ee886f

The open-access MAF lists 89 somatic variants for this specimen: 63 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 23, Frame Shift Del 5, 5'Flank 3, Nonsense Mutation 3, Splice Region 2, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 229/491 reads (47%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/531 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 290/290 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACE2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 527/530 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs759590772, COSV53025209, COSV53027016; called by muse, mutect2, varscan2
- ANO3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 153/325 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs985723132, COSV99881231; called by muse, varscan2
- ARHGEF4 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 424/424 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs946415096; called by muse, mutect2, varscan2
- ATP1A3 | c.244G>A p.A82T (on ENST00000545399 / NM_001256214.2; = p.A69T on NM_152296.5) | Missense Mutation (SNP) | VAF 339/654 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV57485217; called by muse, varscan2
- BCAM | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 362/762 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs772105916, COSV54303892; called by muse, varscan2
- BRAP | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 159/323 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs750051081, COSV59536293; called by muse, mutect2, varscan2
- C4orf54 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758405101; called by muse, mutect2, varscan2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 266/372 reads (72%) | catalogued as rs730881673; called by mutect2, pindel, varscan2
- CEBPE | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 255/518 reads (49%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.939); catalogued as rs371549805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS4 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 224/506 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV52165511; called by muse, mutect2, varscan2
- CYP4V2 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 280/615 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1346140935; called by muse, mutect2, varscan2
- IPCEF1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 314/678 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs759385017; called by muse, mutect2, varscan2
- KSR2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 393/806 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs548971268, COSV100351462, COSV60366465, COSV60384960; called by muse, mutect2, varscan2
- LAMA2 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 195/437 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs144492513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCC | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 250/546 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs140863211; called by muse, mutect2, varscan2
- NCCRP1 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 357/776 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59212465; called by muse, mutect2, varscan2
- PCDHGA3 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 273/610 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs749119321; called by muse, mutect2, varscan2
- PCDHGB5 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 321/657 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.263); catalogued as rs1272959259, COSV54070154; called by muse, mutect2, varscan2
- PSPC1 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 383/1403 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV58890483; called by muse, mutect2, varscan2
- RANBP9 | c.1411C>G p.Q471E | Missense Mutation (SNP) | VAF 244/519 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV50586414; called by muse, varscan2
- RIN2 | c.1402C>T p.R468W (on ENST00000255006 / NM_001242581.1; = p.R419W on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 382/1323 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs748258275; called by muse, mutect2, varscan2
- SCN2A | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1482814284, COSV51860027; called by muse, mutect2, varscan2
- SF3B2 | c.2328C>T p.D776= | Splice Region (SNP) | VAF 149/326 reads (46%) | catalogued as rs139622723; called by muse, mutect2, varscan2
- TRIM49C | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs544734190, COSV71511161; called by muse, mutect2, varscan2
- TRMU | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 408/792 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs769473991, COSV51989840; called by muse, mutect2, varscan2
- TTC34 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 414/851 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1396584428; called by muse, mutect2, varscan2
- WNT3 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 254/545 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1265723023; called by muse, mutect2, varscan2
- ZMIZ1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 273/609 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57890520; called by muse, mutect2, varscan2
- ZNF593 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 268/580 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.162); catalogued as rs760458854; called by muse, varscan2
- ADGRV1 | c.12941A>G p.D4314G | Missense Mutation (SNP) | VAF 259/521 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AHNAK | c.10541G>T p.G3514V | Missense Mutation (SNP) | VAF 285/560 reads (51%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BCAR1 | c.1596_1597del p.S533* | Frame Shift Del (DEL) | VAF 318/732 reads (43%) | called by mutect2, pindel, varscan2
- CPNE2 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 147/308 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, varscan2
- CPNE2 | c.1461C>G p.S487R | Missense Mutation (SNP) | VAF 294/606 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSNK2A1 | c.535_565del p.A179Mfs*16 | Frame Shift Del (DEL) | VAF 143/419 reads (34%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 241/542 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); called by muse, varscan2
- DNAJB6 | c.560A>T p.N187I | Missense Mutation (SNP) | VAF 261/884 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, varscan2
- E4F1 | c.2189C>A p.A730D | Missense Mutation (SNP) | VAF 418/827 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELOA3C | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGFBP1 | c.600del p.K200Nfs*64 | Frame Shift Del (DEL) | VAF 423/843 reads (50%) | called by mutect2, pindel, varscan2
- LMTK3 | c.1427A>T p.N476I | Missense Mutation (SNP) | VAF 393/824 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAP7D1 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 164/869 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED26 | c.806C>G p.P269R | Missense Mutation (SNP) | VAF 308/696 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MZF1 | c.2170_2202del p.L724_E734del | In Frame Del (DEL) | VAF 144/433 reads (33%) | called by mutect2, pindel, varscan2
- N4BP3 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 34/982 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- NEK11 | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 437/712 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PADI3 | c.1025_1028del p.N342Tfs*50 | Frame Shift Del (DEL) | VAF 205/493 reads (42%) | called by mutect2, pindel*, varscan2
- PBX4 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 244/457 reads (53%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PDIA4 | c.1544_1546del p.I515del (on ENST00000286091 / NM_001371244.1; = p.I514del on NM_004911.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 138/532 reads (26%) | called by pindel, varscan2
- PEX5 | c.1565A>G p.Y522C (on ENST00000420616; = p.Y514C on NM_000319.5) | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PITPNM2 | c.2447G>A p.G816D | Missense Mutation (SNP) | VAF 259/574 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2B | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 159/320 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RIF1 | c.765G>C p.L255F | Missense Mutation (SNP) | VAF 129/311 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RNF19A | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 197/630 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SUMO2 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 179/406 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TMEM26 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 269/538 reads (50%) | called by muse, mutect2, varscan2
- URB2 | c.450_458delinsA p.S151Lfs*18 | Frame Shift Del (DEL) | VAF 240/642 reads (37%) | called by pindel, varscan2*
- USP48 | c.1299A>C p.P433= | Splice Region (SNP) | VAF 150/349 reads (43%) | called by muse, mutect2
- ZNF334 | c.1789dup p.E597Gfs*5 | Frame Shift Ins (INS) | VAF 252/897 reads (28%) | called by mutect2, pindel, varscan2
- ZNF350 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 198/421 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ACSF3 | c.1515T>A p.I505= | Silent (SNP) | VAF 104/502 reads (21%) | called by muse, mutect2, varscan2
- CCNL1 | c.687T>C p.N229= | Silent (SNP) | VAF 310/500 reads (62%) | called by muse, varscan2
- CELF2 | c.132C>T p.V44= (on ENST00000416382 / NM_001025077.3; = p.V51= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 283/570 reads (50%) | catalogued as rs780416243; called by muse, mutect2, varscan2
- CFAP43 | c.3084C>T p.D1028= | Silent (SNP) | VAF 134/278 reads (48%) | catalogued as rs547940672, COSV53377231; called by muse, varscan2
- COL4A6 | c.4725G>A p.S1575= | Silent (SNP) | VAF 936/937 reads (100%) | catalogued as rs754549175; called by muse, mutect2, varscan2
- CSK | c.1278C>T p.D426= | Silent (SNP) | VAF 348/728 reads (48%) | catalogued as rs576918025, COSV54972555; called by muse, mutect2, varscan2
- DCLRE1C | c.633C>G p.G211= (on ENST00000378278 / NM_001350965.2; = p.G96= on NM_022487.4) | Silent (SNP) | VAF 235/478 reads (49%) | called by muse, varscan2
- DNAH14 | c.1140A>G p.S380= (on ENST00000445597; = p.S361= on NM_001145154.3) | Silent (SNP) | VAF 135/216 reads (63%) | called by muse, mutect2, varscan2
- EBF3 | c.1692G>A p.A564= (on ENST00000355311 / NM_001375392.1; = p.A519= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 294/627 reads (47%) | catalogued as rs779933101; called by muse, varscan2
- GIMAP1 | c.495C>T p.Y165= | Silent (SNP) | VAF 640/940 reads (68%) | catalogued as COSV56188838; called by muse, varscan2
- KCNA5 | c.165C>T p.G55= | Silent (SNP) | VAF 491/946 reads (52%) | catalogued as rs112226250; called by muse, mutect2, varscan2
- KCNH7 | c.2934C>T p.H978= | Silent (SNP) | VAF 386/386 reads (100%) | called by muse, mutect2, varscan2
- NLRP4 | c.657C>T p.I219= | Silent (SNP) | VAF 297/613 reads (48%) | catalogued as rs754739238, COSV56711965; called by muse, mutect2, varscan2
- NYAP1 | c.348C>T p.A116= | Silent (SNP) | VAF 447/1372 reads (33%) | called by muse, mutect2, varscan2
- PCDH10 | c.615C>T p.D205= | Silent (SNP) | VAF 232/513 reads (45%) | catalogued as COSV52095504; called by muse, mutect2, varscan2
- PCDHA13 | c.1623C>T p.G541= | Silent (SNP) | VAF 446/902 reads (49%) | catalogued as COSV56513205; called by muse, mutect2, varscan2
- PDE3A | c.1062C>T p.H354= | Silent (SNP) | VAF 244/513 reads (48%) | catalogued as rs773971834, COSV100762467; called by muse, mutect2, varscan2
- PERCC1 | c.30C>T p.C10= | Silent (SNP) | VAF 314/622 reads (50%) | catalogued as rs1204686867; called by muse, mutect2, varscan2
- PPBP | c.108C>T p.S36= | Silent (SNP) | VAF 256/505 reads (51%) | called by muse, mutect2, varscan2
- PPP1R9A | c.3012G>A p.Q1004= | Silent (SNP) | VAF 258/821 reads (31%) | catalogued as rs753056791; called by muse, mutect2, varscan2
- SEC23IP | c.1869G>A p.K623= | Silent (SNP) | VAF 163/310 reads (53%) | called by muse, mutect2, varscan2
- TMEM120A | c.726C>T p.S242= | Silent (SNP) | VAF 310/945 reads (33%) | catalogued as rs782801337, COSV58694499; called by muse, mutect2, varscan2
- USF3 | c.1449C>G p.S483= | Silent (SNP) | VAF 111/623 reads (18%) | called by muse, mutect2, varscan2
- LHX9 | chr1:197916687 G>A | 5'Flank (SNP) | VAF 243/504 reads (48%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:139560 G>A | 5'Flank (SNP) | VAF 317/632 reads (50%) | catalogued as rs761612717; called by muse, mutect2, varscan2
- VKORC1 | chr16:31095473 G>A | 5'Flank (SNP) | VAF 207/408 reads (51%) | catalogued as rs1203462105; called by muse, mutect2, varscan2
